Somatic mutation profile of tumor specimen TCGA-AJ-A8CW-01A (aliquot TCGA-AJ-A8CW-01A-11D-A37N-09) from TCGA case TCGA-AJ-A8CW, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 64.5 years (23,554 days).
Specimen TCGA-AJ-A8CW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88f76343-7682-47c7-95d1-92c0617f11f5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AJ-A8CW-10A (Blood Derived Normal), aliquot TCGA-AJ-A8CW-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f9f4e27-869f-46f9-9298-34a68cfa2055

The open-access MAF lists 815 somatic variants for this specimen: 624 protein-altering or splice-affecting, 166 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 403, Silent 166, Frame Shift Del 141, Nonsense Mutation 31, Frame Shift Ins 24, Intron 14, Splice Site 13, Splice Region 6, In Frame Del 5, 3'UTR 5, 3'Flank 3, 5'UTR 1.

Variants (750 of 815; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 11/34 reads (32%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ATP2A1 | c.2464dup p.R822Pfs*39 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs751365374; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HPS1 | c.972del p.M325Wfs*6 | Frame Shift Del (DEL) | VAF 41/79 reads (52%) | catalogued as rs281865082, CD982691; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KMT2B | c.521del p.P174Qfs*20 | Frame Shift Del (DEL) | VAF 21/53 reads (40%) | catalogued as rs763183959; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.2639+1G>A p.X880_splice | Splice Site (SNP) | VAF 14/26 reads (54%) | catalogued as rs746752313, COSV55557161; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- MYO7A | c.2914C>T p.R972* | Nonsense Mutation (SNP) | VAF 18/28 reads (64%) | catalogued as rs782281371, CM081714, COSV101289259, COSV68687619; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NBN | c.1396del p.R466Gfs*18 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs1349928568; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 5/12 reads (42%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PGM1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as rs770066171, COSV64300954; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs121913287, CM126688, COSV55874568, COSV55924241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/24 reads (58%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPARG | c.556del p.S186Vfs*47 (on ENST00000287820 / NM_015869.5; = p.S156Vfs*47 on NM_005037.7) | Frame Shift Del (DEL) | VAF 12/59 reads (20%) | catalogued as rs587776687; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A1BG | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.344); catalogued as COSV99568548; called by muse, mutect2, varscan2
- AADACL3 | c.762del p.Q255Kfs*14 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs746497630; called by mutect2, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- ABCC12 | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100253045; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 7/22 reads (32%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABR | c.464A>G p.D155G (on ENST00000302538 / NM_021962.5; = p.D118G on NM_001092.5) | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99348385; called by muse, mutect2, varscan2
- ACAP3 | c.1691C>T p.A564V | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1460433500, COSV100329708; called by muse, mutect2, varscan2
- ACLY | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs142738500; called by muse, mutect2, varscan2
- ACOT12 | c.154G>A p.V52I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs753806319, COSV56899386; called by muse, mutect2, varscan2
- ACSM2A | c.1541A>G p.Q514R (on ENST00000219054; = p.Q435R on NM_001308169.2) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV54590799, COSV99525534; called by muse, mutect2, varscan2
- ACTN1 | c.1818C>T p.H606= | Splice Region (SNP) | VAF 17/39 reads (44%) | catalogued as rs1377316508, COSV99518305; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 40/78 reads (51%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAD1 | c.244del p.I82Yfs*6 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs746068816; called by mutect2, varscan2
- ADAMTS2 | c.1793G>A p.R598H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1304320729, COSV99283414; called by muse, mutect2, varscan2
- ADAMTS2 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886060494, COSV51083639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY10 | c.2063A>G p.K688R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV100897009; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB1 | c.3226G>A p.G1076R | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100030127, COSV60103522; called by muse, mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 13/21 reads (62%) | catalogued as rs761350619; called by mutect2, varscan2
- AEBP1 | c.3322G>A p.E1108K | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV56260906; called by muse, mutect2, varscan2
- AFF2 | c.3208C>T p.H1070Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99665570; called by muse, mutect2, varscan2
- AGAP3 | c.375del p.X125_splice (on ENST00000622464; = p.X161_splice on NM_031946.7 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 9/34 reads (26%) | catalogued as rs758833571; called by mutect2, pindel, varscan2
- AGAP3 | c.2113G>A p.V705I (on ENST00000622464; = p.V741I on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.444); catalogued as rs370856580, COSV99070585; called by muse, mutect2, varscan2
- AKAP13 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as rs939363727, COSV100774282; called by muse, mutect2, varscan2
- ALOX5 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs143257667; called by muse, mutect2, varscan2
- ALPK1 | c.3063del p.K1021Nfs*18 | Frame Shift Del (DEL) | VAF 35/94 reads (37%) | catalogued as rs1159828137; called by mutect2, pindel, varscan2
- AMMECR1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53319463; called by muse, mutect2, varscan2
- ANAPC2 | c.1064G>T p.R355L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as rs769202387, COSV100119204; called by muse, mutect2, varscan2
- ANK1 | c.4430G>A p.G1477D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV99226300; called by muse, mutect2, varscan2
- ANP32E | c.416T>C p.L139P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100029742; called by muse, mutect2, varscan2
- AP2A1 | c.2459C>T p.A820V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1295641039, COSV100571229; called by muse, mutect2, varscan2
- APBB3 | c.848C>T p.A283V (on ENST00000357560 / NM_133173.2; = p.A290V on NM_006051.3) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs141902691; called by muse, mutect2, varscan2
- APPL1 | c.460dup p.R154Kfs*4 | Frame Shift Ins (INS) | VAF 16/50 reads (32%) | catalogued as rs749401724; called by mutect2, varscan2
- AQP9 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs752717219, COSV99583139; called by muse, mutect2, varscan2
- ARAP1 | c.1213G>T p.V405L (on ENST00000393609 / NM_001040118.2; = p.V160L on NM_015242.4) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100502096; called by muse, mutect2, varscan2
- ARHGAP21 | c.4271C>T p.P1424L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs774810878, COSV100256519; called by muse, mutect2, varscan2
- ARHGAP4 | c.2578T>C p.S860P | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV100509622; called by muse, mutect2, varscan2
- ARHGEF1 | c.758G>T p.R253L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV100529142; called by muse, mutect2, varscan2
- ARRDC1 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.027); catalogued as rs758383734, COSV65059853; called by muse, mutect2, varscan2
- ASAP3 | c.1544G>A p.G515D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.133); catalogued as COSV100369581; called by muse, mutect2, varscan2
- ASMTL | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs780461596, COSV67244021; called by muse, mutect2, varscan2
- ASPM | c.4399T>C p.S1467P | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV99660882; called by muse, mutect2, varscan2
- ATG14 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.163); catalogued as rs770194612, COSV55956992; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP2B4 | c.1182G>A p.W394* | Nonsense Mutation (SNP) | VAF 19/70 reads (27%) | catalogued as COSV100397932; called by muse, mutect2, varscan2
- ATP6V1D | c.140T>C p.I47T | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99370924; called by muse, mutect2, varscan2
- ATR | c.2320del p.I774Yfs*5 | Frame Shift Del (DEL) | VAF 28/55 reads (51%) | catalogued as rs757500301, CD112378; ClinVar: not provided; called by mutect2, varscan2
- AVPR1B | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100899421, COSV65637866, COSV65638110; called by muse, mutect2
- B9D2 | c.335C>T p.T112M | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as rs1465165250, COSV54683632; called by muse, mutect2, varscan2
- BACE2 | c.1211C>T p.A404V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs761539461, COSV57739263; called by muse, mutect2, varscan2
- BARHL2 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs764468861, COSV100966082; called by muse, mutect2, varscan2
- BCL2L13 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100456365; called by muse, mutect2, varscan2
- BCL9L | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV99419873; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.111); catalogued as COSV57277982, COSV99958998; called by muse, mutect2, varscan2
- BMP15 | c.878T>C p.L293P | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99399467; called by muse, mutect2, varscan2
- BMX | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374705811, COSV100564597; called by muse, mutect2, varscan2
- BNC1 | c.225del p.M76Cfs*14 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs751941533; called by mutect2, pindel, varscan2
- BRCA2 | c.2479A>G p.N827D | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.122); catalogued as COSV101204550; called by muse, mutect2, varscan2
- BRINP2 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1218128208, COSV64176360; called by muse, mutect2, varscan2
- C12orf29 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV100469440; called by muse, mutect2, varscan2
- C1orf189 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 16/158 reads (10%) | catalogued as COSV100634300; called by muse, mutect2
- C3orf22 | c.89G>A p.R30K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1446271165, COSV100559544, COSV100559570; called by muse, mutect2, varscan2
- C4orf17 | c.692A>G p.H231R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100431063; called by muse, mutect2, varscan2
- C5orf22 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1326620474, COSV57597891; called by muse, mutect2, varscan2
- C8orf74 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100262259; called by muse, mutect2, varscan2
- CACNA1I | c.4366C>T p.R1456C | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs763242832, COSV100361139; called by muse, mutect2, varscan2
- CAPN10 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV99550468; called by muse, mutect2, varscan2
- CAPN5 | c.986G>A p.R329Q (on ENST00000456580; = p.R289Q on NM_004055.5) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.388); catalogued as COSV99582420; called by muse, mutect2, varscan2
- CARMIL3 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs1358087493, COSV57724850; called by muse, mutect2, varscan2
- CASP14 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as rs942483699, COSV99693101; called by muse, mutect2, varscan2
- CASP5 | c.533del p.N178Ifs*8 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs765105588; called by mutect2, varscan2
- CASZ1 | c.4675G>A p.V1559M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as rs915304591, COSV100985710; called by muse, mutect2, varscan2
- CAVIN1 | c.875C>T p.T292M | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as rs1370778063, COSV63811883; called by muse, mutect2, varscan2
- CAVIN2 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100414307; called by muse, mutect2, varscan2
- CBLL2 | c.1064T>G p.F355C | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV100081691, COSV60368702; called by muse, mutect2, varscan2
- CBY2 | c.1203G>T p.W401C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100137756; called by muse, mutect2, varscan2
- CCDC171 | c.2588C>T p.A863V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs544298455, COSV99901559; called by muse, mutect2, varscan2
- CCDC51 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as rs745750677, COSV99603237; called by muse, mutect2, varscan2
- CCDC96 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.073); catalogued as COSV100028051; called by muse, mutect2, varscan2
- CCHCR1 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.187); catalogued as COSV100885712; called by muse, mutect2, varscan2
- CCT6A | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99303654; called by muse, mutect2, varscan2
- CD1D | c.425T>C p.L142P | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100939638; called by muse, mutect2, varscan2
- CDC25A | c.1336A>T p.R446* | Nonsense Mutation (SNP) | VAF 9/39 reads (23%) | catalogued as COSV56769745; called by muse, mutect2, varscan2
- CDCP1 | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs762706915, COSV56104676; called by muse, mutect2, varscan2
- CDH11 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51763822, COSV99219381; called by muse, mutect2, varscan2
- CDH23 | c.9941C>T p.T3314M | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs559427378, COSV99822924; called by mutect2, varscan2
- CDK20 | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760931795, COSV57482694; called by muse, mutect2, varscan2
- CDR2L | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100464700; called by muse, mutect2, varscan2
- CFAP44 | c.2665dup p.S889Ffs*2 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | catalogued as rs776033769; called by mutect2, pindel
- CFAP53 | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101275016; called by muse, mutect2, varscan2
- CGN | c.3514G>A p.E1172K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.508); catalogued as rs754629677, COSV54972567, COSV54973345; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNB4 | c.169A>G p.K57E | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.005); catalogued as CM145262, COSV99929502; called by muse, mutect2, varscan2
- CHRNG | c.490T>C p.C164R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101264008; called by muse, mutect2, varscan2
- CHTOP | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.876); catalogued as rs1557941638, COSV100904705; called by muse, mutect2, varscan2
- CIZ1 | c.793T>C p.S265P | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs151058866, COSV99477034; called by muse, mutect2, varscan2
- CLK2 | c.1252C>T p.R418C (on ENST00000368361 / NM_001294339.2; = p.R417C on NM_003993.4) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs1410623667, COSV56945990; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 8/45 reads (18%) | catalogued as rs369752219; called by mutect2, varscan2
- CLPS | c.131G>A p.C44Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52566780, COSV99463868; called by muse, mutect2, varscan2
- CLTB | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV100125069; called by muse, mutect2, varscan2
- CLUAP1 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs145377972; called by muse, mutect2, varscan2
- CNTN3 | c.2704+1G>A p.X902_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as rs763671270, COSV55170985, COSV99725644, COSV99726218; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | catalogued as rs374805044; called by mutect2, varscan2
- COL24A1 | c.2357G>A p.G786E | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228415666, COSV100993802; called by muse, varscan2
- COL3A1 | c.2066C>T p.A689V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100483551; called by muse, mutect2
- COL4A4 | c.3247C>A p.P1083T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.043); catalogued as COSV100307434; called by muse, mutect2, varscan2
- COL6A1 | c.352G>T p.D118Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100720382; called by muse, mutect2, varscan2
- COP1 | c.1911G>T p.K637N | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as COSV100443720; called by muse, mutect2, varscan2
- CORO2B | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.498); catalogued as COSV99963615; called by muse, mutect2, varscan2
- CPD | c.2861C>G p.T954R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99853159; called by muse, mutect2, varscan2
- CPE | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101291666; called by muse, mutect2, varscan2
- CPZ | c.1816G>T p.G606C (on ENST00000360986 / NM_001014447.3; = p.G595C on NM_003652.3) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as COSV100249160; called by muse, mutect2, varscan2
- CRHR2 | c.202T>C p.F68L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.014); catalogued as COSV100530112; called by muse, mutect2, varscan2
- CRK | c.777G>T p.E259D | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV100315728; called by muse, mutect2, varscan2
- CROCC | c.673G>C p.E225Q | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100978343; called by muse, mutect2, varscan2
- CSMD3 | c.7903C>T p.P2635S (on ENST00000297405 / NM_001363185.1; = p.P2531S on NM_052900.3) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV52099999, COSV52223769; called by muse, mutect2, varscan2
- CWF19L2 | c.665T>C p.V222A | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99979580; called by muse, mutect2
- CXCL3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.987); catalogued as COSV56018244; called by muse, mutect2, varscan2
- DBX1 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 23/42 reads (55%) | catalogued as COSV99910272; called by muse, mutect2, varscan2
- DCAF8L1 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as rs1368406319, COSV101491519; called by muse, mutect2, varscan2
- DDB1 | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100074773; called by muse, mutect2, varscan2
- DDR1 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.68); catalogued as rs1348414326, COSV61324553; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 28/61 reads (46%) | catalogued as rs766714372; called by mutect2, varscan2
- DEDD2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs781250383, COSV60140880; called by mutect2, varscan2
- DENND2C | c.2584C>T p.R862C (on ENST00000393274 / NM_001256404.2; = p.R805C on NM_198459.4) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs767958216, COSV67924724; called by muse, mutect2, varscan2
- DENND4C | c.5038C>T p.R1680* (on ENST00000434457 / NM_001330640.2; = p.R1631* on NM_017925.7) | Nonsense Mutation (SNP) | VAF 10/27 reads (37%) | catalogued as rs143290383; called by muse, mutect2, varscan2
- DESI2 | c.352-1G>T p.X118_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99798331; called by muse, mutect2, varscan2
- DGKZ | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs1241662894, COSV58992905; called by muse, mutect2, varscan2
- DIP2C | c.3173G>A p.R1058H | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1181953927, COSV99793168; called by muse, mutect2, varscan2
- DLGAP1 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100232924; called by muse, mutect2, varscan2
- DLGAP2 | c.1158C>G p.S386R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.51); catalogued as rs891168310, COSV101422498; called by muse, mutect2, varscan2
- DLK1 | c.1081G>A p.V361I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.061); catalogued as rs746155706, COSV100375073, COSV57991318; called by muse, mutect2, varscan2
- DMAP1 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 17/45 reads (38%) | catalogued as COSV100261791; called by muse, mutect2, varscan2
- DMRT1 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101206696; called by muse, mutect2, varscan2
- DMXL2 | c.8100G>A p.W2700* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV99197381; called by mutect2, varscan2
- DNM3 | c.2033G>A p.R678Q (on ENST00000355305 / NM_001350206.2; = p.R672Q on NM_015569.5) | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.593); catalogued as rs576583368, COSV62457907; called by muse, mutect2, varscan2
- DNMT3A | c.2246G>A p.R749H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs34843713, COSV53064275, COSV53079921; called by muse, mutect2, varscan2
- DNMT3B | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52416099; called by mutect2, varscan2
- DOK4 | c.707G>A p.R236Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.573); catalogued as rs142650688; called by muse, mutect2, varscan2
- DPH6 | c.505+1G>A p.X169_splice | Splice Site (SNP) | VAF 14/28 reads (50%) | catalogued as rs755677220, COSV99853803; called by muse, mutect2, varscan2
- DPP6 | c.1256C>T p.T419M (on ENST00000377770 / NM_001364500.2; = p.T357M on NM_001936.5) | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs1479523542, COSV100127239; called by muse, mutect2, varscan2
- DPYSL2 | c.1281+1G>A p.X427_splice | Splice Site (SNP) | VAF 27/44 reads (61%) | catalogued as COSV60784375; called by muse, mutect2, varscan2
- DPYSL3 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1291512141, COSV100575310; called by muse, mutect2, varscan2
- DRD2 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV100669972; called by muse, mutect2, varscan2
- DTX4 | c.1527del p.G510Afs*35 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs762133243; called by mutect2, varscan2
- DUSP1 | c.426del p.M143Wfs*7 | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV53320819; called by mutect2, pindel, varscan2
- DYNC1H1 | c.8848G>A p.V2950I | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs1321995457, COSV64135603; called by muse, mutect2, varscan2
- ECE1 | c.1810G>A p.V604I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.47); catalogued as rs375453974; called by muse, mutect2, varscan2
- EDC3 | c.992T>C p.V331A | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.24); PolyPhen benign (0.034); catalogued as COSV100166103; called by muse, mutect2, varscan2
- EDEM3 | c.516G>A p.M172I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); catalogued as COSV100545571; called by muse, mutect2
- EFCAB13 | c.1024del p.S342Afs*25 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs759569556; called by mutect2, pindel, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF3E | c.462del p.F154Lfs*13 | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | catalogued as rs1554600455; called by pindel, varscan2
- ELOVL5 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100439827; called by muse, mutect2, varscan2
- EMC2 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as rs761122484, COSV55210324, COSV99624424; called by muse, mutect2, varscan2
- EMILIN2 | c.431C>T p.T144I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.298); catalogued as COSV99598762; called by muse, mutect2, varscan2
- ENGASE | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs373709654, COSV56138075; called by muse, mutect2, varscan2
- ENY2 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV99517514; called by muse, mutect2, varscan2
- EPAS1 | c.2402del p.P801Hfs*39 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV55386697; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs775950025; called by mutect2, varscan2
- ESRRG | c.915G>T p.W305C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753608, COSV63161144; called by muse, mutect2, varscan2
- ESYT2 | c.1145T>C p.V382A (on ENST00000613624; = p.V306A on NM_020728.3) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs774026216, COSV99277105; called by muse, mutect2, varscan2
- EVX2 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1216336490, COSV57963050; called by muse, mutect2, varscan2
- EWSR1 | c.1861C>G p.P621A | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.027); catalogued as rs1247538568, COSV58427582; called by muse, mutect2, varscan2
- EXTL3 | c.481C>A p.P161T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.391); catalogued as COSV99594245; called by muse, mutect2
- F13B | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100803382; called by muse, mutect2
- FAIM | c.390+1G>A p.X130_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as COSV100623981; called by muse, mutect2
- FAM214B | c.1153G>A p.V385I | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.934); catalogued as rs1169655049, COSV100521416; called by muse, mutect2, varscan2
- FAM47B | c.1561G>A p.E521K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61454205; called by muse, mutect2, varscan2
- FANCE | c.929del p.P310Qfs*54 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs587778337; ClinVar: not provided; called by mutect2, pindel
- FBN2 | c.3817G>A p.A1273T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as rs1029936357, COSV99329691; called by muse, mutect2, varscan2
- FGD3 | c.421del p.Q141Rfs*33 | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | catalogued as rs1214182725; called by mutect2, pindel, varscan2
- FGFRL1 | c.720G>A p.Q240= | Splice Region (SNP) | VAF 8/21 reads (38%) | catalogued as COSV53260625; called by muse, mutect2, varscan2
- FLG | c.6167C>T p.T2056I | Missense Mutation (SNP) | VAF 34/243 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.307); catalogued as COSV100911933; called by muse, mutect2
- FMN2 | c.2257G>A p.G753R | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as rs367554600, COSV100146673; called by muse, mutect2, varscan2
- FMNL2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV56495232; called by muse, mutect2, varscan2
- FNIP1 | c.1751T>C p.V584A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100330548; called by muse, mutect2, varscan2
- FOXM1 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100700887; called by muse, mutect2, varscan2
- FOXS1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as rs563064487, COSV99640121; called by muse, mutect2, varscan2
- FSTL1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs143843913; called by muse, mutect2, varscan2
- GABRB2 | c.1465C>T p.R489W (on ENST00000274547; = p.R451W on NM_000813.3) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50907457; called by muse, mutect2, varscan2
- GABRD | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs559765850, COSV101059565, COSV66081984; called by muse, mutect2, varscan2
- GABRE | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 10/18 reads (56%) | catalogued as COSV100944336; called by muse, mutect2, varscan2
- GAK | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as rs144664799, COSV100033163; called by muse, mutect2, varscan2
- GALNT10 | c.608del p.F203Sfs*4 | Frame Shift Del (DEL) | VAF 13/54 reads (24%) | catalogued as COSV51733710; called by mutect2, pindel, varscan2
- GALNT17 | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs763584449, COSV100355279, COSV61171454; called by mutect2, varscan2
- GALNTL5 | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV67181174; called by muse, mutect2, varscan2
- GCLC | c.1483+2T>C p.X495_splice (on ENST00000643939; = p.X493_splice on NM_001498.4) | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99988835; called by muse, mutect2, varscan2
- GDPD5 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765378884, COSV100409440; called by muse, mutect2, varscan2
- GPAM | c.1702G>T p.E568* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100788356, COSV62080960; called by muse, mutect2, varscan2
- GPC5 | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.046); catalogued as COSV100995130; called by muse, varscan2
- GPR157 | c.590A>G p.N197S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs745803106, COSV101072591; called by muse, mutect2, varscan2
- H6PD | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs373092914, COSV101072513; called by muse, mutect2, varscan2
- HARS1 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.499); catalogued as rs766756604, COSV56908855; called by muse, mutect2, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 54/110 reads (49%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HECTD3 | c.1708G>A p.V570I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.138); catalogued as COSV100938178; called by muse, mutect2, varscan2
- HK1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV100065058; called by muse, mutect2
- HNRNPA1 | c.622G>T p.G208C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.694); catalogued as COSV52935967, COSV99267792; called by muse, mutect2, varscan2
- HNRNPM | c.508G>T p.G170* | Nonsense Mutation (SNP) | VAF 33/55 reads (60%) | catalogued as COSV100335358, COSV57692610; called by muse, mutect2, varscan2
- HS6ST3 | c.406C>T p.R136C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65002320; called by muse, mutect2, varscan2
- HSPA8 | c.1523-2A>G p.X508_splice | Splice Site (SNP) | VAF 14/32 reads (44%) | catalogued as COSV99914548; called by muse, mutect2, varscan2
- HTT | c.2272G>A p.D758N | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.59); PolyPhen benign (0.005); catalogued as rs1180767981, COSV100751099; called by muse, mutect2, varscan2
- HUWE1 | c.9694C>T p.R3232C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV53334525; called by muse, mutect2, varscan2
- HUWE1 | c.7562G>A p.R2521H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1556939842, COSV53337584; called by muse, mutect2, varscan2
- IFNAR2 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577150, COSV59750892; called by muse, mutect2, varscan2
- IGSF10 | c.17G>A p.R6K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99191449; called by muse, mutect2, varscan2
- IKZF3 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.372); catalogued as rs114183106, COSV53105626, COSV99500031; called by muse, mutect2, varscan2
- IL3RA | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.142); catalogued as rs754323602, COSV58429699; called by muse, varscan2
- ILF3 | c.1677C>T p.V559= | Splice Region (SNP) | VAF 12/24 reads (50%) | catalogued as rs1212676514, COSV51557142; called by muse, mutect2, varscan2
- INTS13 | c.989A>G p.Y330C | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as rs140042804; called by muse, mutect2, varscan2
- IRX5 | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV58059176; called by muse, mutect2, varscan2
- ITGB4 | c.2629A>G p.K877E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99564508; called by muse, mutect2, varscan2
- ITGB6 | c.1294C>T p.H432Y | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.97); PolyPhen benign (0.18); catalogued as COSV99324839; called by muse, mutect2
- ITGB8 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99752041; called by muse, mutect2, varscan2
- ITIH2 | c.547T>C p.Y183H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100623365; called by muse, mutect2, varscan2
- IVD | c.911A>G p.H304R (on ENST00000651168; = p.H301R on NM_002225.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as COSV99991569; called by muse, mutect2, varscan2
- JPH1 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100646719; called by muse, varscan2
- KCNK9 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.775); catalogued as rs1222560554, COSV100270171; called by muse, mutect2, varscan2
- KCNMA1 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698903; called by muse, mutect2, varscan2
- KIAA0100 | c.3542T>C p.V1181A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as COSV101197375; called by muse, mutect2, varscan2
- KIAA1217 | c.1919C>T p.S640L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.993); catalogued as COSV100287021; called by muse, mutect2, varscan2
- KIF26B | c.821G>A p.S274N | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.173); catalogued as COSV101314054; called by muse, mutect2, varscan2
- KIF2B | c.854A>G p.Q285R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52130509, COSV99275925; called by muse, mutect2, varscan2
- KIRREL1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.196); catalogued as COSV63287391; called by muse, mutect2, varscan2
- KLHDC7A | c.2125C>T p.R709W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs374396134; called by muse, mutect2, varscan2
- KLHL20 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52940390; called by muse, mutect2, varscan2
- KLHL25 | c.1492G>T p.G498* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV100563694; called by muse, mutect2, varscan2
- KLHL41 | c.1296dup p.L433Tfs*9 | Frame Shift Ins (INS) | VAF 6/21 reads (29%) | catalogued as rs1288106608; called by mutect2, varscan2
- KNG1 | c.83G>A p.C28Y | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749071050, COSV99405767; called by muse, mutect2, varscan2
- KRCC1 | c.320C>T p.T107M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs779719379, COSV100712856; called by muse, mutect2, varscan2
- KRT34 | c.198del p.S67Afs*17 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | catalogued as rs751417439; called by mutect2, pindel, varscan2
- KRT4 | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as rs1445050793, COSV99543133; called by muse, mutect2, varscan2
- KRT84 | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1207318259, COSV99230861; called by muse, mutect2
- LAMA2 | c.7181C>T p.T2394I | Missense Mutation (SNP) | VAF 34/46 reads (74%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as COSV101370723, COSV70345763; called by muse, mutect2, varscan2
- LAMA3 | c.2047G>T p.G683W | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557415; called by muse, mutect2, varscan2
- LARP1B | c.1524+2T>C p.X508_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99218709; called by muse, mutect2, varscan2
- LAT2 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.217); catalogued as COSV99305908; called by muse, mutect2, varscan2
- LCE2C | c.90del p.K31Nfs*43 | Frame Shift Del (DEL) | VAF 32/176 reads (18%) | catalogued as rs1403571518, COSV64228338; called by mutect2, pindel, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 11/21 reads (52%) | catalogued as rs765287063; called by mutect2, varscan2
- LMNB1 | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 24/44 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.42); catalogued as rs1339262580, COSV99745814; called by muse, mutect2, varscan2
- LRP1 | c.7122G>T p.K2374N | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99676737; called by muse, mutect2, varscan2
- LTBR | c.656del p.P219Qfs*8 | Frame Shift Del (DEL) | VAF 16/40 reads (40%) | catalogued as COSV99965327; called by pindel, varscan2
- MACF1 | c.18554C>T p.T6185M (on ENST00000372915; = p.T4230M on NM_012090.5) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as rs377031601; called by muse, mutect2, varscan2
- MAOB | c.704T>C p.V235A | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100956193; called by muse, mutect2, varscan2
- MAP1A | c.7943G>A p.R2648H | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs570741917, COSV100288311; called by muse, mutect2, varscan2
- MAP2K3 | c.1027C>A p.L343M (on ENST00000342679 / NM_145109.3; = p.L314M on NM_002756.4) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV100384286; called by muse, mutect2, varscan2
- MAP3K15 | c.3341T>C p.F1114S | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV100135361; called by muse, mutect2, varscan2
- MAP3K8 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs754271777, COSV99552267; called by muse, mutect2, varscan2
- MAST4 | c.5068C>T p.R1690* (on ENST00000403625 / NM_001164664.2; = p.R1501* on NM_015183.3) | Nonsense Mutation (SNP) | VAF 14/32 reads (44%) | catalogued as rs909691151, COSV99844046; called by muse, mutect2, varscan2
- MBD2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV56499805; called by muse, mutect2, varscan2
- MBNL3 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 39/82 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs1249396128, COSV100898508, COSV63731945; called by muse, mutect2, varscan2
- MEN1 | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.498); catalogued as COSV53648196, COSV99581423; called by muse, mutect2, varscan2
- MEP1A | c.1457T>A p.F486Y | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100042981; called by muse, mutect2, varscan2
- MMUT | c.1909G>T p.G637* | Nonsense Mutation (SNP) | VAF 30/50 reads (60%) | catalogued as CM060349, COSV99222490; called by muse, mutect2, varscan2
- MOS | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.029); catalogued as rs1421842842, COSV61336285; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 12/22 reads (55%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRPL2 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 35/61 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.024); catalogued as COSV99432359; called by muse, mutect2, varscan2
- MRPL32 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as COSV99786294; called by muse, mutect2, varscan2
- MTA1 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as rs960530953, COSV100495395; called by muse, mutect2, varscan2
- MTCL1 | c.3429G>T p.K1143N (on ENST00000306329 / NM_001378206.1; = p.K824N on NM_015210.4) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100095311; called by muse, mutect2, varscan2
- MUC16 | c.3593C>T p.T1198M | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs145987902; called by muse, mutect2, varscan2
- MXD4 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100455938; called by muse, mutect2, varscan2
- MYOF | c.4778A>T p.Y1593F | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100826043; called by muse, mutect2, varscan2
- N4BP2L2 | c.1037G>T p.S346I | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV99912659; called by muse, mutect2, varscan2
- NCALD | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV55272708, COSV99637276, COSV99637399; called by muse, mutect2, varscan2
- NCAPH | c.514G>A p.V172I | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as rs543345745, COSV99546080; called by muse, mutect2, varscan2
- NDN | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV100086619; called by muse, mutect2, varscan2
- NDUFV1 | c.923C>T p.T308M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.298); catalogued as rs200925993, COSV100295397; called by muse, mutect2, varscan2
- NETO2 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.066); catalogued as rs749167255, COSV100292553; called by muse, mutect2, varscan2
- NFAT5 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV100591067; called by muse, mutect2, varscan2
- NID2 | c.3407T>C p.L1136P | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.945); catalogued as COSV99357035; called by muse, mutect2, varscan2
- NLGN2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100081197, COSV57209201; called by muse, mutect2, varscan2
- NLGN3 | c.2492C>T p.A831V (on ENST00000358741 / NM_181303.2; = p.A811V on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.045); catalogued as COSV62442401; called by muse, mutect2, varscan2
- NLRP1 | c.3265del p.E1089Rfs*2 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as COSV52562446; called by mutect2, pindel, varscan2
- NLRP10 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV100149892; called by muse, mutect2, varscan2
- NOMO1 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99814783; called by muse, mutect2, varscan2
- NOS1 | c.3001C>T p.R1001W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs755159260, COSV100500342; called by muse, mutect2, varscan2
- NOS1 | c.2027del p.G676Afs*64 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | catalogued as rs746543323; called by pindel, varscan2
- NPC1 | c.808G>A p.V270I | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1357930161, COSV99341736; called by muse, mutect2, varscan2
- NPIPB15 | c.1231C>T p.R411C | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.366); catalogued as rs770434420, COSV101466031; called by muse, varscan2
- NR5A1 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV65294867; called by muse, mutect2, varscan2
- NRG3 | c.1729C>T p.P577S (on ENST00000404547 / NM_001370084.1; = p.P553S on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs900344857, COSV64546853; called by muse, mutect2, varscan2
- NTNG1 | c.308del p.P103Lfs*3 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1266119883; called by mutect2, pindel, varscan2
- NUP62 | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs761071949, COSV61312291; called by muse, mutect2, varscan2
- OBSCN | c.4751C>T p.A1584V | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.826); catalogued as COSV99482423; called by muse, mutect2, varscan2
- OBSCN | c.8845C>T p.R2949C | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as rs1286746468, COSV99482425; called by muse, mutect2, varscan2
- OCRL | c.1856C>A p.P619H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100843519; called by muse, mutect2, varscan2
- OPN1LW | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1557157979, COSV100885060; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 27/53 reads (51%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10A7 | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs759572005, COSV100406616; called by muse, mutect2, varscan2
- OR1L1 | c.831G>T p.K277N (on ENST00000373686; = p.K227N on NM_001005236.3) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV100542251, COSV58935361; called by muse, varscan2
- OR1L1 | c.875G>A p.G292D (on ENST00000373686; = p.G242D on NM_001005236.3) | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV58936446; called by muse, varscan2
- OR56A1 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV100360524; called by muse, mutect2, varscan2
- OR6B1 | c.667G>A p.A223T | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs778385912, COSV101281667; called by muse, mutect2, varscan2
- OTOGL | c.3326T>C p.L1109S (on ENST00000547103; = p.L1100S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.89); catalogued as COSV101509466; called by muse, mutect2, varscan2
- P3H1 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs771866490, COSV99355459; called by muse, mutect2, varscan2
- PAFAH1B1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV101250442; called by muse, mutect2, varscan2
- PANX1 | c.482G>A p.R161H | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs576747452, COSV57133518, COSV57135619; called by muse, mutect2, varscan2
- PAQR8 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.927); catalogued as COSV62443126; called by muse, mutect2, varscan2
- PARD3B | c.3205A>G p.N1069D (on ENST00000406610 / NM_001302769.2; = p.N1000D on NM_057177.7) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.026); catalogued as COSV100594652; called by muse, mutect2, varscan2
- PCDH10 | c.679dup p.Q227Pfs*19 | Frame Shift Ins (INS) | VAF 6/12 reads (50%) | catalogued as rs762465989; called by mutect2, varscan2
- PCDH15 | c.4822A>G p.N1608D (on ENST00000644397 / NM_001354429.2; = p.N1550D on NM_001142771.2) | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV64688917; called by muse, mutect2, varscan2
- PCDHA10 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.841); catalogued as rs782361309, COSV56538086; called by muse, mutect2, varscan2
- PCDHA2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs150299243; called by muse, mutect2, varscan2
- PCDHA5 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.15); catalogued as COSV100972067; called by muse, mutect2, varscan2
- PCDHA9 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65327057; called by muse, mutect2, varscan2
- PCDHB11 | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.788); catalogued as rs112871983, COSV61311341; called by muse, mutect2, varscan2
- PCDHB14 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99506173; called by muse, mutect2, varscan2
- PCDHGB6 | c.2017C>T p.P673S | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.566); catalogued as COSV53993192; called by muse, mutect2
- PCNX2 | c.6179C>T p.S2060L | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99268909; called by muse, mutect2, varscan2
- PGGHG | c.1191G>T p.W397C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV101164631; called by muse, mutect2, varscan2
- PHB | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303230; called by muse, mutect2, varscan2
- PHF3 | c.5039T>C p.M1680T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100013750; called by muse, mutect2, varscan2
- PIK3R1 | c.1156C>G p.R386G (on ENST00000521381 / NM_181523.3; = p.R116G on NM_181504.4) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57126203, COSV57144628; called by muse, mutect2, varscan2
- PITX1 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99530709; called by muse, mutect2, varscan2
- PKD1L1 | c.4132G>A p.V1378M | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as rs769015726, COSV99220936; called by muse, mutect2, varscan2
- PKDREJ | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV53552462; called by muse, mutect2, varscan2
- PKHD1 | c.11573C>T p.T3858I | Missense Mutation (SNP) | VAF 46/82 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV100945013; called by muse, mutect2, varscan2
- PKMYT1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.627); catalogued as rs780368070, COSV99234188; called by muse, mutect2, varscan2
- PLA2G3 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.049); catalogued as COSV99311173; called by muse, mutect2, varscan2
- PLA2G4F | c.2302C>T p.R768C | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs560812368, COSV51829190; called by muse, mutect2, varscan2
- PLCXD2 | c.122del p.P41Lfs*47 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs1290783500; called by mutect2, pindel, varscan2
- PLEKHG3 | c.2948T>G p.L983R (on ENST00000394691; = p.L1039R on NM_001308147.2) | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV99906939; called by muse, mutect2, varscan2
- PLEKHH2 | c.90A>C p.Q30H | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99174988; called by muse, mutect2, varscan2
- PLEKHH3 | c.574del p.V192Wfs*6 | Frame Shift Del (DEL) | VAF 26/33 reads (79%) | catalogued as rs778393033; called by mutect2, varscan2
- PLOD3 | c.876dup p.Q293Afs*48 | Frame Shift Ins (INS) | VAF 12/28 reads (43%) | catalogued as rs746342377; called by mutect2, varscan2
- PLXNB2 | c.4033C>T p.R1345C | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775464863, COSV63780989; called by muse, mutect2, varscan2
- PLXND1 | c.3078-3del | Splice Region (DEL) | VAF 9/22 reads (41%) | catalogued as rs1278682279; called by mutect2, pindel, varscan2
- PODN | c.1433G>A p.R478H (on ENST00000395871; = p.R430H on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs146352896; called by muse, mutect2, varscan2
- POLR3A | c.4138G>A p.D1380N | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as rs143800893; called by muse, mutect2, varscan2
- POTEE | c.2057del p.K686Rfs*6 | Frame Shift Del (DEL) | VAF 30/112 reads (27%) | catalogued as rs772047281; called by mutect2, varscan2
- PPP1R14D | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202066593, COSV54543326; called by muse, mutect2, varscan2
- PPP2CB | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV99646545; called by muse, mutect2, varscan2
- PPP2R2B | c.1190del p.G397Afs*31 (on ENST00000394409; = p.G463Afs*31 on NM_181674.2) | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs767808084; called by mutect2, pindel, varscan2
- PPRC1 | c.3917dup p.M1309Dfs*47 | Frame Shift Ins (INS) | VAF 14/31 reads (45%) | catalogued as rs749215431; called by mutect2, varscan2
- PRLHR | c.700T>C p.Y234H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492900; called by muse, mutect2, varscan2
- PRPF3 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs782324840, COSV100255039; called by muse, mutect2, varscan2
- PTH2R | c.45G>A p.M15I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55920979; called by muse, mutect2, varscan2
- PTOV1 | c.923C>T p.P308L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159017736, COSV99681944, COSV99682098; called by muse, mutect2, varscan2
- PTPN18 | c.830_833del p.T277Rfs*115 | Frame Shift Del (DEL) | VAF 5/25 reads (20%) | catalogued as rs758129770; called by pindel, varscan2
- PWWP2A | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100194049; called by muse, mutect2
- PXMP4 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99459449; called by muse, mutect2, varscan2
- RAD50 | c.3496C>T p.R1166W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs587782577, COSV54756960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAD54B | c.2371G>A p.A791T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.081); catalogued as COSV100280082; called by muse, mutect2, varscan2
- RAI1 | c.1690A>G p.M564V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV99884711; called by muse, mutect2, varscan2
- RALGDS | c.797C>T p.A266V | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100924523; called by muse, mutect2, varscan2
- RANBP3 | c.181C>T p.H61Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.063); catalogued as rs1405924698, COSV99222445; called by muse, mutect2, varscan2
- RANBP9 | c.1313C>T p.P438L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99163603; called by muse, mutect2, varscan2
- RARA | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99565274; called by muse, mutect2, varscan2
- RASGRF2 | c.3668C>T p.T1223M | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.402); catalogued as rs369787079; called by muse, mutect2, varscan2
- RASSF2 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs748168721, COSV65082559; called by muse, mutect2, varscan2
- RASSF8 | c.107G>A p.R36Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.218); catalogued as rs200480939, COSV51454009, COSV51455341; called by muse, mutect2, varscan2
- RBBP6 | c.3868C>T p.R1290* | Nonsense Mutation (SNP) | VAF 20/48 reads (42%) | catalogued as COSV60504283; called by muse, mutect2, varscan2
- RBM3 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.078); catalogued as rs782338747, COSV100618775; called by muse, mutect2, varscan2
- RBM47 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.106); catalogued as rs768544332, COSV55931033; called by muse, mutect2, varscan2
- RBPMS | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55121828, COSV55123193; called by muse, mutect2, varscan2
- RECQL4 | c.854del p.P285Hfs*8 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | catalogued as rs1292831710; called by mutect2, pindel, varscan2
- RERE | c.4019C>T p.A1340V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.383); catalogued as COSV61952032; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | catalogued as rs753959887; called by mutect2, varscan2
- RFX5 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.435); catalogued as rs777652681, COSV100923921; called by muse, mutect2, varscan2
- RHOXF2B | c.349C>T p.Q117* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV101003945, COSV101003972; called by muse, mutect2, varscan2
- RNF144B | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV99464919; called by muse, mutect2, varscan2
- RNF17 | c.2278T>C p.Y760H | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99694060; called by muse, mutect2, varscan2
- RNF220 | c.1298del p.G433Afs*4 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | catalogued as COSV59189938; called by mutect2, pindel, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 19/24 reads (79%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RNF6 | c.1778del p.L593Yfs*2 | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | catalogued as rs1199638878, COSV60419447; called by mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RRBP1 | c.2098C>T p.R700C (on ENST00000377813 / NM_001365613.2; = p.R267C on NM_004587.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs41276396, COSV99854374; called by muse, mutect2, varscan2
- RREB1 | c.3526G>A p.G1176R | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763924130, COSV100619701, COSV100619920; called by muse, varscan2
- RRP12 | c.3272G>T p.R1091I | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.157); catalogued as rs1480453748, COSV100213372; called by muse, mutect2, varscan2
- RTL5 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.035); catalogued as COSV101030263; called by muse, mutect2, varscan2
- RYR1 | c.7726G>A p.A2576T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.658); catalogued as rs767394054, COSV62089628; called by muse, mutect2, varscan2
- S100A10 | c.224T>G p.L75R | Missense Mutation (SNP) | VAF 75/97 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV100916734; called by muse, mutect2, varscan2
- SAMD9L | c.303del p.N103Ifs*35 | Frame Shift Del (DEL) | VAF 15/53 reads (28%) | catalogued as COSV100560358, COSV59083322; called by mutect2, pindel, varscan2
- SASH3 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.04); catalogued as rs777927882, COSV63555653; called by muse, mutect2, varscan2
- SCARA3 | c.1141G>A p.V381M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as rs774402743, COSV57271257, COSV57271691; called by muse, mutect2, varscan2
- SCML2 | c.1931A>T p.D644V | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99319376; called by muse, mutect2, varscan2
- SEC16A | c.4042G>A p.V1348I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as rs766515410, COSV51529344; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SECISBP2L | c.1816C>A p.H606N (on ENST00000559471 / NM_001193489.2; = p.H561N on NM_014701.4) | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV99960788; called by muse, mutect2
- SELENOO | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.771); catalogued as COSV101096993; called by muse, mutect2, varscan2
- SEPTIN2 | c.497C>T p.A166V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs748465376, COSV63472276; called by muse, mutect2, varscan2
- SGPL1 | c.1589A>G p.Q530R | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV100940433; called by muse, mutect2, varscan2
- SHPRH | c.495del p.E166Nfs*3 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as rs1469942319; called by mutect2, varscan2
- SLAIN2 | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.549); catalogued as COSV99971802; called by muse, mutect2, varscan2
- SLC12A1 | c.1193C>T p.A398V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100372478; called by muse, mutect2, varscan2
- SLC12A2 | c.3227T>C p.L1076P | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99321419; called by muse, mutect2, varscan2
- SLC13A5 | c.43G>A p.V15M | Missense Mutation (SNP) | VAF 29/59 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1223974189, COSV99546090; called by muse, mutect2, varscan2
- SLC25A31 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.854); catalogued as rs778830237, COSV99829556; called by muse, mutect2, varscan2
- SLC27A3 | c.1705C>T p.R569W (on ENST00000271857; = p.R441W on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as rs772719483, COSV99669875; called by muse, mutect2, varscan2
- SLC2A1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.027); catalogued as rs763241827, COSV65287672, COSV65288549; ClinVar: likely benign; called by muse, varscan2
- SLC2A12 | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562200282, COSV99260362; called by muse, mutect2, varscan2
- SLC30A8 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.124); catalogued as COSV101438711; called by muse, mutect2, varscan2
- SLC35F2 | c.865A>G p.T289A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56183403, COSV99758508; called by muse, mutect2, varscan2
- SLC37A1 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779216363, COSV100721788, COSV100721858; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC49A3 | c.758C>T p.A253V (on ENST00000404286 / NM_001294341.2; = p.A252V on NM_032219.4) | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as COSV100448530, COSV100448568; called by muse, mutect2, varscan2
- SLC5A1 | c.1177T>A p.S393T | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV99833659; called by muse, mutect2, varscan2
- SLC6A19 | c.1303A>G p.N435D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.364); catalogued as COSV100443664; called by muse, mutect2, varscan2
- SLCO5A1 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); catalogued as COSV99480669; called by muse, mutect2, varscan2
- SMC1B | c.403G>T p.V135F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1421414551, COSV100663413; called by muse, mutect2, varscan2
- SMCHD1 | c.4108C>T p.R1370C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.013); catalogued as rs942559171, COSV55255217; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- SMPD4 | c.2462C>T p.S821L (on ENST00000409031 / NM_017951.4; = p.S792L on NM_017751.4) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs1432615634, COSV100302661; called by muse, mutect2, varscan2
- SMURF2 | c.1798G>T p.A600S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99300952; called by muse, mutect2, varscan2
- SORL1 | c.1193G>A p.G398D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99494970; called by muse, mutect2, varscan2
- SOX3 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV100983742; called by muse, mutect2, varscan2
- SP140 | c.2015del p.K672Rfs*4 | Frame Shift Del (DEL) | VAF 26/54 reads (48%) | catalogued as rs746109620; called by mutect2, varscan2
- SPATA1 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747813776, COSV99759853; called by muse, mutect2, varscan2
- SPATA12 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.162); catalogued as COSV100534714; called by muse, mutect2, varscan2
- SPATS2L | c.1613C>T p.T538M | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs775380668, COSV100660834; called by muse, mutect2, varscan2
- SPIDR | c.189G>A p.P63= | Splice Region (SNP) | VAF 122/255 reads (48%) | catalogued as rs966816902; called by muse, mutect2, varscan2
- SPRYD3 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 32/73 reads (44%) | catalogued as rs752934275, COSV100036847; called by muse, mutect2, varscan2
- SPSB2 | c.532C>A p.L178M | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); catalogued as COSV99222971; called by muse, mutect2, varscan2
- SPTA1 | c.4106del p.K1369Sfs*7 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | catalogued as rs1161647781; called by mutect2, pindel, varscan2
- SPTBN1 | c.3082G>A p.D1028N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as rs545815578, COSV100443164; called by muse, mutect2, varscan2
- SRMS | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.298); catalogued as rs761225720, COSV53920606; called by muse, mutect2, varscan2
- SRRM2 | c.6179G>A p.R2060Q | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs201485562, COSV99241641; called by muse, varscan2
- ST6GAL2 | c.1481G>A p.R494H | Missense Mutation (SNP) | VAF 16/23 reads (70%) | PolyPhen benign (0.362); catalogued as rs757962368, COSV62418156; called by muse, mutect2, varscan2
- STAMBP | c.446T>C p.V149A | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV100277769; called by muse, mutect2, varscan2
- STAT3 | c.1756A>G p.M586V | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99233064; called by muse, mutect2, varscan2
- STK25 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99885172; called by muse, mutect2, varscan2
- STON2 | c.2566C>T p.P856S (on ENST00000649389 / NM_001366849.2; = p.P799S on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50848831; called by muse, mutect2, varscan2
- SYNE1 | c.23602C>T p.H7868Y (on ENST00000367255 / NM_182961.4; = p.H7797Y on NM_033071.3) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55027005, COSV99574062; called by muse, mutect2, varscan2
- SYNPO2 | c.1886C>T p.P629L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs372370554, COSV100205574, COSV100206212; called by muse, mutect2, varscan2
- SYT14 | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.73); PolyPhen benign (0.168); catalogued as rs796524658, COSV99655818; called by muse, mutect2, varscan2
- TAF1L | c.3180G>T p.E1060D | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.134); catalogued as COSV99645197; called by muse, mutect2, varscan2
- TANGO6 | c.3086del p.G1029Dfs*10 | Frame Shift Del (DEL) | VAF 14/38 reads (37%) | catalogued as COSV55768301; called by mutect2, pindel, varscan2
- TAX1BP3 | c.332G>A p.R111Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs747198869, COSV50440048; called by muse, mutect2, varscan2
- TBC1D10C | c.960del p.A321Rfs*100 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | catalogued as rs751687887; called by mutect2, pindel, varscan2
- TBC1D24 | c.1039G>A p.V347M (on ENST00000646147 / NM_001199107.2; = p.V341M on NM_020705.3) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.871); catalogued as rs371031447; ClinVar: uncertain significance; called by muse, varscan2
- TBC1D24 | c.1117C>A p.L373M (on ENST00000646147 / NM_001199107.2; = p.L367M on NM_020705.3) | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV99565209; called by muse, varscan2
- TBC1D2B | c.2477T>C p.L826P | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100317575; called by muse, mutect2, varscan2
- TBC1D5 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs375749909, COSV99509879; called by muse, mutect2, varscan2
- TBC1D8B | c.2122A>G p.R708G | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.598); catalogued as rs1181065808, COSV99344869; called by muse, mutect2, varscan2
- TBCD | c.3140T>C p.L1047P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100833603; called by muse, mutect2, varscan2
- TCTN3 | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs780438906, COSV99797399; called by muse, mutect2, varscan2
- TDRD5 | c.58A>G p.I20V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.892); catalogued as rs543279481, COSV99676836; called by muse, mutect2, varscan2
- TECPR1 | c.2648del p.G883Afs*23 | Frame Shift Del (DEL) | VAF 14/41 reads (34%) | catalogued as rs762459209; called by mutect2, pindel, varscan2
- TENM1 | c.3154G>T p.G1052C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV100950527; called by muse, mutect2
- TFAP4 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 14/33 reads (42%) | catalogued as COSV99200085; called by muse, mutect2, varscan2
- TFCP2L1 | c.383G>A p.R128Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs925313655, COSV55289068; called by muse, mutect2, varscan2
- TFE3 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1411173446, COSV59945949; called by muse, mutect2, varscan2
- TIAM1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs867133208, COSV99737813; called by muse, mutect2, varscan2
- TICRR | c.2792G>A p.R931Q | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.396); catalogued as rs527745752, COSV51545657; called by muse, mutect2, varscan2
- TIMM50 | c.443A>G p.Y148C | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100068034, COSV58679269; called by muse, mutect2
- TJP1 | c.2137G>C p.V713L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100633004; called by muse, mutect2, varscan2
- TLN1 | c.3425C>T p.T1142M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.194); catalogued as rs778948183, COSV100148078; called by mutect2, varscan2
- TM4SF5 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99564781; called by muse, mutect2, varscan2
- TMEM147 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.724); catalogued as COSV99382925; called by muse, mutect2, varscan2
- TMEM60 | c.231del p.A78Pfs*11 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs749773249; called by mutect2, varscan2
- TNK2 | c.3068C>T p.A1023V | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV100361577, COSV57369700; called by muse, mutect2, varscan2
- TNR | c.638T>G p.V213G | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.243); catalogued as COSV99690824; called by muse, mutect2, varscan2
- TNS3 | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs200656291; called by muse, mutect2, varscan2
- TOLLIP | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99719659; called by muse, mutect2, varscan2
- TP53RK | c.680C>A p.T227N | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV100927779; called by muse, mutect2, varscan2
- TPRG1L | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV99573451; called by muse, mutect2, varscan2
- TRIM71 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs1292700294, COSV67470738; called by muse, mutect2, varscan2
- TRIM8 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs753886521, COSV56660036; called by muse, mutect2, varscan2
- TRPC7 | c.574C>T p.R192W | Missense Mutation (SNP) | VAF 11/18 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as COSV61459219; called by muse, mutect2, varscan2
- TRPM3 | c.1040C>T p.S347L (on ENST00000357533 / NM_001366142.2; = p.S192L on NM_020952.6) | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1258641236, COSV62467272; called by muse, mutect2, varscan2
- TRRAP | c.5725C>T p.L1909F (on ENST00000359863 / NM_001244580.1; = p.L1891F on NM_003496.3) | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100722762; called by muse, mutect2, varscan2
- TRRAP | c.7940C>T p.A2647V (on ENST00000359863 / NM_001244580.1; = p.A2629V on NM_003496.3) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100722763; called by muse, mutect2, varscan2
- TRRAP | c.8758C>T p.R2920W (on ENST00000359863 / NM_001244580.1; = p.R2902W on NM_003496.3) | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs139373663; called by muse, mutect2, varscan2
- TSC2 | c.4351C>T p.R1451C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.53); catalogued as rs369553241, COSV51927010, COSV99238702; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- TTC3 | c.5179G>T p.V1727L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV100695875; called by muse, mutect2, varscan2
- TTC7A | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs779629005, COSV55415019; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TUBGCP3 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as rs186110739, COSV56186599; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs760251146; called by mutect2, varscan2
- UBA7 | c.1039C>T p.R347W | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.696); catalogued as rs746497550, COSV100339835; called by muse, mutect2, varscan2
- UBE3B | c.728C>T p.A243V | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV99784304; called by muse, mutect2, varscan2
- UBQLN2 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs749463696, CM128868, COSV57739680, COSV57739722; called by muse, mutect2, varscan2
- UBR7 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.957); catalogued as rs267604099, COSV50148800; called by muse, mutect2, varscan2
- UNK | c.350A>G p.E117G | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53143575, COSV99505403; called by muse, mutect2, varscan2
- USH2A | c.11821C>T p.R3941W | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs749942414, COSV56326680; called by muse, mutect2, varscan2
- USP26 | c.1044del p.F348Lfs*7 | Frame Shift Del (DEL) | VAF 34/84 reads (40%) | catalogued as CM077651, COSV63708747; called by mutect2, varscan2
- USP34 | c.6297G>T p.M2099I | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV101277140; called by muse, mutect2, varscan2
- USP6NL | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs750244541, COSV99510002; called by mutect2, varscan2
- UTP14A | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.029); catalogued as COSV100928994; called by muse, mutect2, varscan2
- UTP20 | c.392del p.L131* | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs761528888; called by mutect2, varscan2
- UTP25 | c.2141C>T p.T714M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs140967197; called by muse, mutect2, varscan2
- VARS2 | c.1048G>A p.V350I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.447); catalogued as rs773112651, COSV52557919, COSV52558540; called by muse, mutect2, varscan2
- VPS13A | c.1115del p.K372Sfs*2 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs770350986; called by mutect2, varscan2
- VPS13A | c.8653dup p.Y2885Lfs*2 | Frame Shift Ins (INS) | VAF 23/51 reads (45%) | catalogued as rs775734065; called by mutect2, varscan2
- VPS13D | c.4451-1G>A p.X1484_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99167850; called by muse, mutect2, varscan2
- VRTN | c.983dup p.V329Rfs*25 | Frame Shift Ins (INS) | VAF 19/47 reads (40%) | catalogued as rs749358571; called by mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs756173793; called by mutect2, varscan2
- WASHC2C | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs1554861044, COSV100314162; called by muse, mutect2, varscan2
- WASHC5 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV100572983; called by muse, mutect2, varscan2
- WDTC1 | c.868del p.E290Nfs*8 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as rs747972901, COSV60089251; called by mutect2, varscan2
- WHAMM | c.809G>A p.G270D | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99725129; called by muse, mutect2, varscan2
- WHRN | c.751C>T p.P251S | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs1483291111, COSV99470524; called by muse, mutect2
- WWC3 | c.2418G>T p.E806D | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as COSV66505943; called by muse, mutect2, varscan2
- WWOX | c.65G>A p.W22* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs979241689, COSV100880564; called by muse, mutect2, varscan2
- XYLT1 | c.1078G>A p.V360M | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1238696157, COSV99762872; called by muse, mutect2, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 9/23 reads (39%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZFC3H1 | c.2590G>T p.A864S | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.645); catalogued as COSV101110661; called by muse, mutect2, varscan2
- ZMIZ2 | c.1423G>A p.E475K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV54810235; called by muse, mutect2, varscan2
- ZMYM2 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 18/46 reads (39%) | catalogued as COSV101243996; called by muse, mutect2, varscan2
- ZNF142 | c.1306C>T p.R436C (on ENST00000411696 / NM_001379660.1; = p.R236C on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as rs749831295, COSV68742936; called by muse, mutect2, varscan2
- ZNF236 | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99470949; called by muse, mutect2
- ZNF337 | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1404723330, COSV99430352; called by muse, mutect2, varscan2
- ZNF407 | c.5149G>A p.D1717N | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as rs1436407647, COSV55257358; called by muse, mutect2, varscan2
- ZNF45 | c.5C>T p.T2M | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as rs756350135, COSV99524223; called by muse, mutect2, varscan2
- ZNF470 | c.517C>T p.H173Y | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.82); PolyPhen benign (0.133); catalogued as COSV100401345; called by muse, mutect2, varscan2
- ZNF516 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.026); catalogued as rs554378029, COSV101487344; called by muse, varscan2
- ZNF608 | c.2449C>T p.R817* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as rs1467008438, COSV100102241; called by muse, mutect2, varscan2
- ZNF608 | c.1394C>G p.A465G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as rs755205166; called by muse, mutect2, varscan2
- ZNF7 | c.692del p.K231Sfs*59 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | catalogued as rs1398210459; called by mutect2, pindel, varscan2
- ZNF71 | c.1267G>A p.A423T | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs774584964, COSV60147820, COSV60148004; called by muse, mutect2, varscan2
- ZNF786 | c.2330T>C p.I777T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100302943; called by muse, mutect2, varscan2
- ZNF862 | c.2510T>C p.F837S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.063); catalogued as rs942609955, COSV99783700; called by muse, varscan2
- ZNF862 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV99783704; called by muse, varscan2
- ZNF99 | c.258G>A p.W86* | Nonsense Mutation (SNP) | VAF 11/26 reads (42%) | catalogued as rs1396483863, COSV101233911; called by muse, mutect2, varscan2
- ZSCAN5A | c.179A>G p.Q60R | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.988); catalogued as COSV99570501; called by muse, mutect2, varscan2
- ADAMTS6 | c.2465T>G p.I822S | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- AL645922.1 | c.1630del p.V544* | Frame Shift Del (DEL) | VAF 27/57 reads (47%) | called by mutect2, pindel, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, varscan2
- ARID1A | c.4220del p.P1407Qfs*74 | Frame Shift Del (DEL) | VAF 15/37 reads (41%) | called by mutect2, pindel, varscan2
- BTN1A1 | c.104del p.P35Rfs*75 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | called by mutect2, pindel, varscan2
- CCDC8 | c.43del p.R15Gfs*27 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- CD6 | c.1424dup p.E476* | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- CEP170 | c.1442del p.N481Ifs*26 | Frame Shift Del (DEL) | VAF 26/168 reads (15%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, varscan2
- CLK3 | c.1072_1074del p.E358del (on ENST00000395066 / NM_001130028.1; = p.E210del on NM_003992.4) | In Frame Del (DEL) | VAF 14/44 reads (32%) | called by mutect2, pindel, varscan2
- CNST | c.388del p.S130Qfs*7 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel, varscan2
- CNTNAP5 | c.3006del p.F1002Lfs*17 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | called by mutect2, pindel, varscan2
- COX7C | c.159_162del p.F53Lfs*2 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2
- CPEB2 | c.2941del p.C981Vfs*31 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel, varscan2
- CSMD1 | c.6321del p.Q2108Nfs*13 (on ENST00000520002; = p.Q2107Nfs*13 on NM_033225.6) | Frame Shift Del (DEL) | VAF 37/90 reads (41%) | called by mutect2, pindel, varscan2
- CT45A3 | c.490T>A p.S164T | Missense Mutation (SNP) | VAF 25/209 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- DAP3 | c.1134del p.E379Sfs*5 | Frame Shift Del (DEL) | VAF 13/58 reads (22%) | called by mutect2, pindel, varscan2
- DMTN | c.281del p.P94Hfs*137 | Frame Shift Del (DEL) | VAF 35/74 reads (47%) | called by mutect2, pindel, varscan2
- DNAH5 | c.13458del p.F4486Lfs*7 | Frame Shift Del (DEL) | VAF 41/91 reads (45%) | called by mutect2, varscan2
- DOCK11 | c.848del p.K283Rfs*4 | Frame Shift Del (DEL) | VAF 57/141 reads (40%) | called by mutect2, pindel, varscan2
- DYRK3 | c.160_162del p.S54del | In Frame Del (DEL) | VAF 15/91 reads (16%) | called by mutect2, pindel, varscan2
- EAPP | c.374del p.K125Rfs*55 | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | called by mutect2, varscan2
- EZHIP | c.473del p.P158Rfs*46 | Frame Shift Del (DEL) | VAF 18/40 reads (45%) | called by mutect2, pindel, varscan2
- F5 | c.66del p.S23Afs*9 | Frame Shift Del (DEL) | VAF 16/57 reads (28%) | called by mutect2, pindel, varscan2
- FCGBP | c.439A>T p.T147S | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- FER1L6 | c.5562_5564del p.V1855del | In Frame Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, varscan2
- FILIP1L | c.1814del p.N605Tfs*3 (on ENST00000354552 / NM_182909.3; = p.N365Tfs*3 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/53 reads (34%) | called by mutect2, pindel, varscan2
- GJA1 | c.450dup p.L151Vfs*16 | Frame Shift Ins (INS) | VAF 12/73 reads (16%) | called by mutect2, pindel, varscan2
- GLO1 | c.180del p.K60Nfs*7 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- HFM1 | c.4193del p.D1398Vfs*27 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- HNRNPA2B1 | c.7-4_7-3del | Splice Region (DEL) | VAF 12/54 reads (22%) | called by pindel, varscan2
- HPS4 | c.747del p.F249Lfs*2 | Frame Shift Del (DEL) | VAF 12/33 reads (36%) | called by mutect2, pindel, varscan2
- IDE | c.1706dup p.L569Ffs*9 | Frame Shift Ins (INS) | VAF 26/54 reads (48%) | called by mutect2, varscan2
- IFRD1 | c.1113del p.K371Nfs*35 | Frame Shift Del (DEL) | VAF 32/82 reads (39%) | called by mutect2, pindel, varscan2
- IPPK | c.569_572del p.K190Rfs*7 | Frame Shift Del (DEL) | VAF 17/50 reads (34%) | called by pindel, varscan2
- ITGAX | c.1444del p.H482Ifs*44 | Frame Shift Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, varscan2
- KCNG1 | c.367del p.A123Pfs*6 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- KIF15 | c.3243del p.K1081Nfs*13 | Frame Shift Del (DEL) | VAF 13/28 reads (46%) | called by mutect2, pindel, varscan2
- KIF21A | c.387dup p.H130Tfs*5 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | called by mutect2, varscan2
- KLHL20 | c.1408G>A p.G470R | Missense Mutation (SNP) | VAF 33/171 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | called by mutect2, varscan2
- KMT2B | c.2290_2291del p.P764Vfs*81 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel*, varscan2
- LARP1 | c.1978del p.D660Tfs*12 (on ENST00000518297 / NM_033551.3; = p.D583Tfs*12 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | called by mutect2, pindel, varscan2
- LGALS13 | c.44_47del p.S15Lfs*5 | Frame Shift Del (DEL) | VAF 13/47 reads (28%) | called by mutect2, pindel, varscan2
- LZTR1 | c.1491del p.G498Afs*58 | Frame Shift Del (DEL) | VAF 18/42 reads (43%) | called by mutect2, pindel, varscan2
- MACF1 | c.1003dup p.I335Nfs*6 | Frame Shift Ins (INS) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- MAN2B2 | c.1183del p.R395Vfs*37 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.932dup p.M312Dfs*14 | Frame Shift Ins (INS) | VAF 6/47 reads (13%) | called by mutect2, pindel, varscan2
- MED12 | c.6285_6293del p.Q2113_Q2115del | In Frame Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- MPRIP | c.1058del p.P353Qfs*30 | Frame Shift Del (DEL) | VAF 23/73 reads (32%) | called by mutect2, pindel, varscan2
- MRM1 | c.770-1G>T p.X257_splice | Splice Site (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- MVK | c.417del p.A141Rfs*18 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- MYO10 | c.2512_2513del p.E838Kfs*35 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by pindel, varscan2
- NANOG | c.260del p.K87Rfs*46 | Frame Shift Del (DEL) | VAF 19/61 reads (31%) | called by mutect2, pindel, varscan2
- NHS | c.3596del p.N1199Tfs*6 | Frame Shift Del (DEL) | VAF 5/38 reads (13%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.3800A>G p.D1267G | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- NR2C1 | c.751del p.T251Lfs*6 | Frame Shift Del (DEL) | VAF 20/64 reads (31%) | called by mutect2, pindel, varscan2
- NR3C1 | c.1168dup p.S390Ffs*2 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- NSD1 | c.4455del p.V1486* | Frame Shift Del (DEL) | VAF 17/52 reads (33%) | called by mutect2, pindel, varscan2
- NUFIP1 | c.1449del p.F483Lfs*22 | Frame Shift Del (DEL) | VAF 28/82 reads (34%) | called by mutect2, pindel, varscan2
- OTP | c.339del p.A114Hfs*30 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- PARVA | c.468del p.K156Nfs*13 | Frame Shift Del (DEL) | VAF 15/48 reads (31%) | called by mutect2, pindel, varscan2
- PEX13 | c.213del p.F71Lfs*40 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- PIK3R1 | c.1067del p.L356Wfs*17 (on ENST00000521381 / NM_181523.3; = p.L86Wfs*17 on NM_181504.4) | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- PML | c.78del p.E27Rfs*71 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- POU2F1 | c.2050_2051del p.L684Afs*7 (on ENST00000541643 / NM_001365848.1; = p.L707Afs*7 on NM_002697.4) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by pindel, varscan2
- PPAT | c.1116dup p.F373Ifs*9 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, varscan2
- PPP6C | c.329del p.L110Cfs*10 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel, varscan2
- PRKN | c.1212dup p.A405Sfs*164 | Frame Shift Ins (INS) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- PTPN23 | c.2249del p.P750Lfs*53 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | called by mutect2, pindel, varscan2
- RGS22 | c.2742del p.K914Nfs*18 | Frame Shift Del (DEL) | VAF 30/67 reads (45%) | called by mutect2, pindel, varscan2
- RYR2 | c.5235dup p.H1746Tfs*27 | Frame Shift Ins (INS) | VAF 11/57 reads (19%) | called by mutect2, pindel, varscan2
- SCAMP2 | c.679del p.C227Vfs*3 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- SCN10A | c.2124del p.F708Lfs*32 | Frame Shift Del (DEL) | VAF 27/52 reads (52%) | called by mutect2, pindel, varscan2
- SGSM2 | c.1653+1del | Frame Shift Del (DEL) | VAF 7/14 reads (50%) | called by mutect2, varscan2
- SLC10A3 | c.53del p.G18Afs*9 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | called by mutect2, pindel, varscan2
- SLC35F1 | c.258_260del p.E86del | In Frame Del (DEL) | VAF 26/47 reads (55%) | called by pindel, varscan2
- SOGA3 | c.1535dup p.A513Gfs*11 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | called by mutect2, varscan2
- SOX6 | c.878del p.P293Lfs*3 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- SUN2 | c.1863del p.T622Qfs*5 | Frame Shift Del (DEL) | VAF 16/41 reads (39%) | called by mutect2, pindel, varscan2
- TGM6 | c.1078del p.Q360Rfs*99 | Frame Shift Del (DEL) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- THBD | c.1360del p.V454Cfs*52 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- TMPRSS5 | c.1278del p.R427Vfs*15 | Frame Shift Del (DEL) | VAF 19/45 reads (42%) | called by mutect2, pindel, varscan2
- TMTC3 | c.1198del p.S400Vfs*14 | Frame Shift Del (DEL) | VAF 11/42 reads (26%) | called by mutect2, pindel, varscan2
- TRAPPC12 | c.56dup p.Q20Sfs*23 | Frame Shift Ins (INS) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- TRIM9 | c.1983del p.F661Lfs*10 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- UBR4 | c.8406del p.M2803Cfs*16 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | called by mutect2, pindel, varscan2
- USP33 | c.1776dup p.C593Mfs*12 | Frame Shift Ins (INS) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- XRN1 | c.4831del p.R1611Gfs*34 | Frame Shift Del (DEL) | VAF 13/30 reads (43%) | called by mutect2, pindel, varscan2
- ZC3H11A | c.1280del p.K427Rfs*8 | Frame Shift Del (DEL) | VAF 13/76 reads (17%) | called by mutect2, pindel, varscan2
- ZFC3H1 | c.1155del p.K385Nfs*9 | Frame Shift Del (DEL) | VAF 9/32 reads (28%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2536dup p.R846Pfs*65 | Frame Shift Ins (INS) | VAF 11/31 reads (35%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.480_481del p.S162Yfs*16 | Frame Shift Del (DEL) | VAF 14/26 reads (54%) | called by pindel, varscan2
- ZNF131 | c.979del p.I327Ffs*45 (on ENST00000509156 / NM_001330707.2; = p.I293Ffs*45 on NM_003432.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel
- ABCC12 | c.2814G>A p.V938= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs752005424, COSV100253044; called by muse, mutect2, varscan2
- ACAD9 | c.1342C>T p.L448= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100459339; called by muse, mutect2, varscan2
- ADORA1 | c.888C>T p.R296= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs201811129, COSV99704644; called by muse, varscan2
- AHDC1 | c.3813G>A p.P1271= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs376593773; called by muse, mutect2, varscan2
- AP2A2 | c.2709C>T p.C903= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs202109923, COSV100173222; called by muse, mutect2, varscan2
- APLN | c.120C>T p.R40= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as rs745409842, COSV100278313; called by muse, mutect2, varscan2
- APOB | c.1089C>T p.V363= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV99267101; called by muse, mutect2, varscan2
- ARCN1 | c.57A>T p.R19= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV99873871; called by muse, mutect2, varscan2
- ARMCX2 | c.675G>A p.T225= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1556061231, COSV57530679; called by muse, mutect2, varscan2
- ATXN2 | c.3159G>A p.Q1053= (on ENST00000550104; = p.Q893= on NM_002973.4) | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs371508391; called by muse, mutect2, varscan2
- ATXN2L | c.2997G>C p.G999= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs778627616, COSV57366176, COSV57377668; called by muse, mutect2, varscan2
- BIN1 | c.54G>A p.V18= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1312715933, COSV99388360; called by muse, varscan2
- C3AR1 | c.978C>T p.D326= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs1453300461, COSV50817778; called by muse, mutect2
- CAMTA1 | c.576C>T p.C192= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs757970256, COSV57899609; called by muse, mutect2, varscan2
- CCDC185 | c.1530G>A p.A510= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as rs146271498; called by muse, mutect2, varscan2
- CCDC88B | c.495C>T p.L165= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV57267040; called by muse, mutect2, varscan2
- CCER1 | c.738G>A p.L246= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV62648985; called by muse, mutect2, varscan2
- CCKBR | c.1335C>T p.G445= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs143732620, COSV58106289; called by muse, mutect2, varscan2
- CDH23 | c.1263C>T p.Y421= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs528720730, COSV99820499; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH3 | c.2475C>T p.G825= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs543214840, COSV99868895; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH4 | c.438G>A p.P146= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as rs776758212, COSV100849383; called by muse, mutect2, varscan2
- CEP170 | c.2763C>T p.P921= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100317597; called by muse, mutect2, varscan2
- CHRDL1 | c.1347C>T p.H449= (on ENST00000372045; = p.H455= on NM_145234.4) | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV99488513; called by muse, mutect2, varscan2
- CLASRP | c.1680C>T p.A560= | Silent (SNP) | VAF 63/189 reads (33%) | catalogued as rs555928251, COSV99674050; called by muse, mutect2, varscan2
- CRIM1 | c.1983A>G p.S661= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as COSV99754136; called by muse, mutect2
- CSF2RA | c.357C>A p.T119= | Silent (SNP) | VAF 40/95 reads (42%) | catalogued as COSV100817887, COSV62625112; called by muse, mutect2, varscan2
- CTTNBP2NL | c.210C>T p.G70= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs775374920, COSV54744238; called by muse, mutect2, varscan2
- CUX2 | c.1752G>A p.S584= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as rs539297356, COSV99920369; called by muse, mutect2, varscan2
- CYP7B1 | c.129C>T p.P43= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as rs1471365409, COSV59589698; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAXX | c.1653G>A p.Q551= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV99802476; called by muse, mutect2, varscan2
- DIPK2A | c.150G>A p.L50= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV100237385; called by muse, mutect2, varscan2
- DISC1 | c.1170G>A p.L390= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54407529, COSV99698364; called by muse, mutect2, varscan2
- DLST | c.699C>G p.R233= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99472087; called by muse, mutect2, varscan2
- DNAH10 | c.4368T>C p.I1456= (on ENST00000409039; = p.I1395= on NM_207437.3) | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV101292486; called by muse, mutect2, varscan2
- DNAJB1 | c.846C>T p.P282= | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs754645758, COSV99584223; called by muse, mutect2, varscan2
- E2F2 | c.1149G>A p.Q383= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as COSV100674850; called by muse, mutect2, varscan2
- EIF4E2 | c.234T>C p.Y78= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs751146807, COSV99299256; called by muse, mutect2, varscan2
- ELF1 | c.414C>A p.T138= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV99523257; called by muse, mutect2, varscan2
- EPB41L3 | c.840A>G p.A280= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100549920; called by muse, mutect2, varscan2
- EPB41L4B | c.1377G>A p.Q459= | Silent (SNP) | VAF 21/32 reads (66%) | catalogued as COSV101000575; called by muse, mutect2, varscan2
- EPHB1 | c.2898G>A p.L966= | Silent (SNP) | VAF 31/60 reads (52%) | catalogued as COSV101213872; called by muse, mutect2, varscan2
- EPHX1 | c.1063C>T p.L355= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV99689144; called by muse, mutect2
- FAM47B | c.483C>T p.D161= | Silent (SNP) | VAF 43/96 reads (45%) | catalogued as rs779441369, COSV100264524; called by muse, mutect2, varscan2
- FAM83E | c.978G>A p.P326= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs766951316, COSV99572375; called by muse, mutect2, varscan2
- FBXO33 | c.535C>T p.L179= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99981000; called by muse, mutect2, varscan2
- FRS2 | c.162A>G p.S54= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs1203874084, COSV100166266; called by muse, mutect2, varscan2
- GAL3ST3 | c.303C>T p.C101= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs201726501, COSV100360950; called by muse, mutect2, varscan2
- GCN1 | c.7557G>A p.A2519= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs372015112; called by muse, mutect2, varscan2
- GPR155 | c.1926G>A p.Q642= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99790127; called by muse, mutect2, varscan2
- GSX2 | c.114G>A p.P38= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as rs1177565067, COSV58843151; called by muse, mutect2, varscan2
- GTF3C2 | c.2568G>T p.G856= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99273144; called by muse, mutect2, varscan2
- HECW1 | c.2304G>A p.P768= | Silent (SNP) | VAF 27/64 reads (42%) | catalogued as rs780363076, COSV67831753; called by muse, mutect2, varscan2
- HECW1 | c.3225C>T p.S1075= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs757763095, COSV101224127; called by muse, mutect2, varscan2
- HERC2 | c.5181G>A p.L1727= | Silent (SNP) | VAF 20/146 reads (14%) | catalogued as COSV99875861; called by muse, mutect2, varscan2
- HHIPL1 | c.291C>A p.A97= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100415296; called by muse, mutect2, varscan2
- HJURP | c.13C>T p.L5= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV101366377; called by muse, mutect2, varscan2
- HLCS | c.1227C>T p.S409= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as rs771923409, COSV100358475; called by muse, mutect2, varscan2
- HMCN1 | c.10956A>G p.V3652= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV99633553; called by muse, mutect2, varscan2
- HS3ST3B1 | c.1119G>A p.R373= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as rs755360402, COSV100714580; called by muse, mutect2, varscan2
- IP6K3 | c.168G>T p.L56= | Silent (SNP) | VAF 45/76 reads (59%) | catalogued as COSV99540034; called by muse, mutect2, varscan2
- ISL1 | c.597C>T p.C199= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV57933041; called by muse, mutect2, varscan2
- ISLR2 | c.1708C>T p.L570= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV100679723; called by muse, mutect2, varscan2
- ITGAE | c.1935C>T p.F645= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs371911996; called by muse, mutect2, varscan2
- ITPR2 | c.5757G>A p.Q1919= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs776821983, COSV101190103; called by muse, mutect2, varscan2
- KATNB1 | c.1104C>T p.D368= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs201625277, COSV101109304; called by muse, mutect2, varscan2
- KCND2 | c.153C>T p.R51= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV58580848; called by muse, mutect2, varscan2
- KDM1A | c.1788G>T p.T596= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100752759; called by muse, mutect2, varscan2
- KIAA0319L | c.2697G>A p.S899= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs1280128170, COSV100357606; called by muse, mutect2, varscan2
- KIF24 | c.2637C>T p.S879= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV99903436; called by muse, mutect2, varscan2
- KIFAP3 | c.1989T>C p.Y663= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100847087; called by muse, mutect2, varscan2
- KLK11 | c.216C>T p.F72= (on ENST00000594768 / NM_144947.3; = p.F40= on NM_006853.3) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as rs765126785, COSV51576892; called by muse, mutect2, varscan2
- LIPI | c.351C>T p.F117= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as rs548960957, COSV60708768; called by muse, mutect2, varscan2
- LLGL2 | c.909C>T p.G303= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV99390259; called by muse, mutect2, varscan2
- MAGEA1 | c.297A>C p.R99= | Silent (SNP) | VAF 39/93 reads (42%) | catalogued as COSV100756667; called by muse, mutect2, varscan2
- MAGEA4 | c.486C>T p.I162= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs1478626384, COSV52342915, COSV99367655; called by muse, mutect2
- MIEF2 | c.612G>A p.P204= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as rs772020431; called by muse, varscan2
- MROH1 | c.522C>T p.G174= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as rs899493354, COSV58193650; called by muse, mutect2, varscan2
- MSR1 | c.1335T>C p.A445= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV100027747; called by muse, mutect2, varscan2
- MTCL1 | c.5118C>T p.S1706= (on ENST00000306329 / NM_001378206.1; = p.S1387= on NM_015210.4) | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as rs1335666321, COSV100095313; called by muse, mutect2, varscan2
- MTSS1 | c.1656C>T p.S552= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as rs781571240, COSV52675233; called by muse, mutect2, varscan2
- MUC16 | c.26646G>T p.R8882= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV101200701; called by muse, mutect2, varscan2
- MUC2 | c.447C>T p.Y149= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs561164943; called by muse, mutect2
- MYLK3 | c.2178C>T p.N726= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV101189177; called by muse, mutect2, varscan2
- NMRAL1 | c.799A>C p.R267= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV99361876; called by muse, mutect2, varscan2
- NOS3 | c.396C>T p.N132= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV99871991; called by muse, mutect2, varscan2
- NOTCH4 | c.3375C>T p.C1125= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs1439403733, COSV100900878, COSV66681372; called by muse, mutect2, varscan2
- NUDT11 | c.201C>T p.Y67= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs61729271, COSV101047096; called by muse, mutect2, varscan2
- OAZ1 | c.231C>A p.I77= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100457403; called by muse, mutect2, varscan2
- OR52A5 | c.39G>A p.A13= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as rs755800182, COSV100263526; called by muse, varscan2
- P3H2 | c.408C>T p.R136= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV60018935; called by muse, mutect2, varscan2
- PAPSS2 | c.510G>T p.G170= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV100753633; called by muse, mutect2, varscan2
- PAXIP1 | c.3045C>T p.H1015= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV101249980; called by muse, mutect2, varscan2
- PCDH15 | c.4302G>A p.A1434= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs368622542; called by muse, varscan2
- PCDH17 | c.1371G>A p.S457= | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV64972215; called by muse, mutect2, varscan2
- PCDHA8 | c.474C>T p.S158= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as rs782380474, COSV100970719; called by muse, mutect2, varscan2
- PCDHB15 | c.1443C>T p.G481= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV99179095; called by muse, mutect2, varscan2
- PDK2 | c.96C>T p.S32= | Silent (SNP) | VAF 39/75 reads (52%) | catalogued as rs1202108729, COSV99143039; called by muse, mutect2, varscan2
- PHETA1 | c.108G>A p.R36= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV100825393; called by muse, mutect2, varscan2
- PIK3C2B | c.4200C>A p.T1400= | Silent (SNP) | VAF 18/74 reads (24%) | catalogued as COSV100916197; called by muse, mutect2, varscan2
- PIK3C2G | c.45C>T p.H15= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs145139332; called by muse, mutect2, varscan2
- PKD1 | c.6243C>T p.A2081= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs370526001; called by muse, mutect2, varscan2
- PKN3 | c.717G>A p.L239= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV99403852; called by muse, mutect2, varscan2
- PKP1 | c.1882C>T p.L628= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1292205177, COSV99825579; called by muse, mutect2, varscan2
- PPIL2 | c.951T>C p.D317= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100622710; called by muse, mutect2, varscan2
- PRAMEF18 | c.753C>T p.S251= | Silent (SNP) | VAF 32/320 reads (10%) | called by muse, mutect2
- PRG4 | c.522T>C p.S174= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100825886; called by muse, mutect2, varscan2
- PSAPL1 | c.408G>A p.A136= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs767261815, COSV100040616; called by muse, mutect2, varscan2
- PTCHD3 | c.1299G>A p.L433= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV101438948; called by muse, mutect2, varscan2
- PXDNL | c.3369C>A p.T1123= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100685342; called by muse, mutect2, varscan2
- RAI1 | c.843G>A p.Q281= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs748280748, COSV55388680, COSV55398332; called by muse, varscan2
- RAI2 | c.243G>A p.L81= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100518176, COSV100518483; called by muse, mutect2, varscan2
- RANBP2 | c.8289T>A p.A2763= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99312867; called by mutect2, varscan2
- RIMKLB | c.564G>A p.A188= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as rs757692505, COSV55239173, COSV55240072; called by muse, mutect2, varscan2
- RNASE10 | c.459C>T p.N153= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100116039; called by muse, mutect2, varscan2
- RNF114 | c.36G>A p.A12= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs944756575, COSV99724860; called by muse, mutect2, varscan2
- RREB1 | c.1782G>A p.T594= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1299817097, COSV58558795; called by muse, varscan2
- RYR2 | c.14523C>A p.I4841= | Silent (SNP) | VAF 24/105 reads (23%) | catalogued as COSV63720385, COSV63723221; called by muse, mutect2, varscan2
- SASH3 | c.396G>A p.E132= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV100795282; called by muse, mutect2, varscan2
- SEC16A | c.5655G>A p.R1885= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as COSV99259739; called by muse, mutect2, varscan2
- SETD1A | c.4239C>T p.R1413= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs759173261, COSV99353515; called by muse, mutect2, varscan2
- SEZ6L2 | c.2709G>A p.T903= (on ENST00000308713 / NM_001114099.3; = p.T846= on NM_012410.4) | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as rs201249042, COSV100435703; called by muse, mutect2, varscan2
- SIM2 | c.630G>T p.L210= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99293499; called by muse, mutect2, varscan2
- SLC44A4 | c.928C>T p.L310= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs1319347483, COSV99999161; called by muse, mutect2, varscan2
- SLC51A | c.934C>T p.L312= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as rs1240466505, COSV99492364; called by muse, mutect2, varscan2
- SLITRK3 | c.840C>A p.L280= | Silent (SNP) | VAF 20/49 reads (41%) | catalogued as rs376735384, COSV99579798; called by muse, mutect2, varscan2
- SMG1 | c.1683G>A p.L561= | Silent (SNP) | VAF 81/195 reads (42%) | catalogued as rs779835583, COSV101246656; called by muse, mutect2, varscan2
65 further variants in this file (0 protein-altering or splice-affecting, 40 silent, 25 other) are not listed here.
